Surgical pathology report (de-identified scan), TCGA case TCGA-CG-5723, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-5723-01A (Primary Tumor).

*** Diagnosis(es): ***

Total gastrectomy specimen including an extensively ulcerated, weakly differentiated gastric adenocarcinoma of maximum diameter 5 cm located in the area of the cardia with only very localized signet ring cell differentiation and with infiltration of the perigastric fatty tissue and one regional lymph node metastasis. Tumor-free esophageal resection margin lined with typical squamous epithelium and tumor-free aboral resection margin lined with unremarkable duodenal mucosa.

Tumor stage: pT2b pN1 (1/31) pMX;

Source: NCI Genomic Data Commons file eedc0ccb-4268-42b4-a3a2-392c7eed594d (TCGA-CG-5723.6C70E081-A28E-4B7A-9C9A-6099E1946009.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).